CCDI case PBCDGZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/312d9550-6cd6-41ce-a16e-f2b810ad7a8f

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Retinoblastoma, NOS: ICD-O-3 morphology code: 9510/3; Tissue or organ of origin: Retina; Age at diagnosis: 3.7 years (1,348 days).

Biospecimens (3 samples)
- Sample 0DPHSW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPHT6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQ5ZS: Tissue type: Tumor; Specimen type: Solid Tissue.
